Gene-level copy-number profile of tumor specimen TCGA-2G-AAFZ-01A from TCGA case TCGA-2G-AAFZ, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 32.2 years (11,761 days).
Specimen TCGA-2G-AAFZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.86eb51b7-d9b0-4d42-a187-095149c478cb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAFZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/68d27267-9e74-430a-beb2-ddf09a38d3bc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 335; copy number 4: 36,487; copy number 5: 5,481; copy number 6: 12,958; copy number 7: 1,051; copy number 8: 1,967; copy number 10: 690; copy number 11: 297; copy number 13: 553.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAFZ-01A-11D-A42X-01): tumor purity 0.91, ploidy 2.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,540 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:388,412–38,067,142, 619 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr2:45,164,816–48,776,517, 70 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr2:48,632,856–48,633,353, 1 gene, copy number 10: TPT1P11.
- chr12:66,767–34,249,958, 850 genes, copy number 11–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
